FM case AD14770 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Thymus.
https://portal.gdc.cancer.gov/cases/c9713e1e-cf45-422a-8a13-7fa5c6d7c355

Female, 45.9 years: Carcinoma, NOS (ICD-O-3 8010/3) of the thymus; primary biopsied or resected from the thymus. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
